Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SH, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SH-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY REPORT

* Final Report *

CHC
Carcinoma, urothelial NOS
path
Carcinoma, transitional cell
Site Bladder NOS
8/20/13
8/20/13
067.9
QW 8/26/14

Document Type:
*Date - Date of Service:
Document Status:
Document Title:
Encounter info:
Contributor system:

* Final Report *

ORDERING PHYSICIAN:
Ordering Physician:

PRE-OPERATIVE DIAGNOSIS:
Bladder CA

POST-OPERATIVE DIAGNOSIS:
Same as preop

MICROSCOPIC DESCRIPTION:
A-B: See final microscopic-diagnosis.

C: Sections of the bladder show a pleomorphic population of transitional cell infiltrating into the detrusor muscle in nests and broad cords. The malignant cells are large and distinct cytoplasmic borders. The cytoplasm is glassy pale and eosinophilic. The nuclei are round to oval, the nuclear pleomorphism is marked and consists of isolated greatly enlarged cells against a background of moderate nuclear sized pleomorphism. Chromatin is coarsely clumped. The chromatin clumping is coarser in the larger cells. Nucleoli are conspicuous, red and occasionally multiple. At the edges of the tumor, cells are present in smaller groups and invade in thin round to oval trabeculae. Mitotic figures are occasionally encountered. Vascular space invasion is identified

Signature Line
Signed by:
ELECTRONIC SIGNATURE

GROSS DESCRIPTION:
A: The specimen is received fresh from the O.R. and labeled "Right ureter F/S." It consists of a 0.8 x 0.5 x 0.3 cm section of ureter. Entirely submitted for frozen section.

B: The specimen is received fresh from the O.R. and labeled "Left ureter F/S." It consists of a 0.8 x 0.5 x 0.2 cm section of ureter. Entirely submitted for frozen

Printed by:
Printed on:

Page 1 of 7
(Continued)

[page 2 of 7]
SURGICAL PATHOLOGY REPORT

* Final Report *

section.

C: The specimen is received fresh from the O.R. and labeled "Bladder, uterus, ovaries & perivesicle nodes." It consists of a 15 x 13 x 5.8 cm anterior exenteration specimen. The uterus measures 9 x 6.2 x 6 cm. The right fallopian tube measures 6.8 cm in length and 0.2 cm in diameter; it is grossly unremarkable. The right ovary measures 2.2 x 1.7 x 0.6 cm and is grossly unremarkable. The left fallopian tube measures 7 cm in length and 0.2 cm in diameter and is grossly unremarkable. The left ovary measures 2.1 x 1.5 x 0.7 cm and is grossly unremarkable. The serosal surface of the uterus is smooth. A subserosa myoma measuring 5 x 3.5 x 3 cm is noted. It displays the usual protuberant whorled white cross section. No areas of hemorrhage or necrosis are noted. The ectocervix measures 2.5 x 2.2 cm and is lined by velvety, tan epithelium. The endocervical canal measures 2.5 cm in length and is lined by velvety, tan epithelium. The endometrial canal measures 4 x 2 x 0.1 cm; it is lined by velvety, tan epithelium. Two polypoid projections are present in the endometrial cavity measuring 0.5 x 0.5 x 0.1 cm and 0.2 x 0.2 x 0.1 cm. The posterior endomyometrial to serosal thickness is 2.2 cm. The anterior endomyometrial serosal thickness is 1.1 cm. The vesico-uterine septum is soft to palpation. There is no gross extension of tumor from the bladder to the cervix. The peritoneal surface overlying the bladder measures 10 x 9 cm and is smooth and shiny. There are no peritoneal tumor implants. The bladder measures 9 x 6.5 x 2 cm and contains a 2.2 x 1.9 x 1.1 cm tumor. The tumor is located 0.7 cm from the urethral margin; it is smooth, firm and white. The surface of the tumor is not papillary. The remaining bladder mucosa is smooth and tan with the exception of a 2.2 x 1.5 cm area of hemorrhagic discoloration superior to the tumor. The left distal ureter measures 1 cm in length and 0.7 cm in circumference and inserts into the tumor. The right distal ureter measures 6 cm in length and 1.1 cm in circumference and inserts directly into the tumor. The bladder wall thickness far from the tumor is 0.6 cm. The bladder wall thickness in the area of tumor is 1.5 cm. The tumor extends to within 0.4 cm of the external surface of detrusor muscle. Representative sections in 21 cassettes.

D: The specimen is received in formalin and labeled "Right periaortic lymph nodes." It consists of a 3.8 x 0.9 x 0.4 cm serpiginous, purple-tan tissue fragment. Entirely submitted in one cassette.

E: The specimen is received in formalin and labeled "Right common iliac nodes." It consists of a 2.8 x 1 x 0.5 cm greasy, yellow tissue fragment. Entirely submitted in one cassette.

F: The specimen is received in formalin and labeled "Right external iliac nodes." Entirely submitted in three cassettes.

G: The specimen is received in formalin and labeled "Right obturator / hypogastric

Printed by:
Printed on:

Page 2 of 7
(Continued)

[page 3 of 7]
SURGICAL PATHOLOGY REPORT

* Final Report *

nodes." It consists of 2.8 x 2.1 x 1.2 cm greasy, yellow tissue. Entirely submitted in one cassette.

H: The specimen is received in formalin and labeled "Left paraaortic lymph nodes." It consists of 2 x 1 x 0.5 cm of greasy, yellow tissue. Entirely submitted in one cassette.

I: The specimen is received in formalin and labeled "Presacral lymph nodes." It consists of 3 x 2 x 0.5 cm of greasy, yellow tissue. Entirely submitted in one cassette.

J: The specimen is received in formalin and labeled "Left common iliac lymph nodes." It consists of 2.5 x 2 x 0.5 cm of greasy, yellow tissue. Entirely submitted in one cassette.

K: The specimen is received in formalin and labeled "Left external iliac lymph nodes." It consists of 4 x 3 x 0.5 cm of greasy, yellow tissue. Entirely submitted in three cassettes.

L: The specimen is received in formalin and labeled "Left obturator / hypogastric lymph nodes." It consists of 4 x 2 x 0.5 cm greasy, yellow tissue. Entirely submitted in three cassettes.

M: The specimen is received in formalin and labeled "Right presciatic lymph nodes." It consists of 1.5 x 0.6 x 0.3 cm of greasy, yellow tissue. Entirely submitted in one cassette.

N: The specimen is received in formalin and labeled "Left presciatic lymph nodes." It consists of 1.7 x 0.5 x 0.3 cm greasy, yellow tissue. Entirely submitted in one cassette.

O: The specimen is received in formalin and labeled "Left proximal ureter." It consists of 1.7 x 0.8 x 0.5 cm of ureter. Entirely submitted in one cassette.

P: The specimen is received in formalin and labeled "Right proximal ureter." It consists of a 2.3 x 0.7 x 0.2 cm segment of ureter. Entirely submitted in one cassette.

Q: The specimen is received in formalin and labeled "Gallbladder." It consists of a 7.6 x 2.7 x 2.7 cm gallbladder. The external surface is smooth. A stone is lodge at the cystic duct measuring 0.7 cm in greatest dimension. The specimen is opened to reveal green liquid bile with no further stones. The cystic duct is opened to reveal a gallstone 0.7 cm in greatest dimension. The gallstone is sectioned to reveal a black interior. The gallbladder is then opened to reveal smooth, tan-yellow epithelium. The epithelium is velvety and there are no

Printed by:
Printed on:

Page 3 of 7
(Continued)

[page 4 of 7]
SURGICAL PATHOLOGY

* Final Report *

papillary projections. Sections of the gallbladder body and cystic duct are submitted in a single cassette.

SECTIONS:

AFS: frozen section, right ureter
BFS: frozen section, left ureter
C1: right tube and ovary
C2: left tube and ovary
C3,4: intramural myoma
C5: posterior cervix
C6: endometrial polyp
C7,8: posterior endomyometrium and serosa
C9: anterior endomyometrium and serosa
C10: hemorrhagic discoloration superior to the tumor
C11: left distal ureter
C12: right ureter and tumor
C13: bladder wall far from tumor
C14,15: tumor
C16,17: tumor and inked margin
C18: anterior cervix
C19: uninvolved mucosa
C20: peritoneum
C21: perivesical fat
D: right periaortic lymph nodes all embedded
E: right common iliac nodes all embedded
F1-3: right external iliac nodes all embedded
G: right obturator/hypogastric nodes all embedded
H: left para-aortic lymph nodes all embedded
I: presacral lymph nodes all embedded
J: left common iliac lymph nodes all embedded
K1-3: left external iliac lymph nodes all embedded
L1-3: left obturator/hypogastric lymph nodes all embedded
M: right presciatic lymph nodes all embedded
N: left presciatic lymph nodes all embedded
O: left proximal ureter all embedded
P: right proximal ureter all embedded
Q: gallbladder

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right ureter:
- no tumor identified

Printed by:
Printed on:

Page 4 of 7
(Continued)

[page 5 of 7]
SURGICAL PATHOLOGY

* Final Report *

BFS: Left ureter:
- no tumor identified
CFA: Urethra:
- no tumor identified

GROSS DIAGNOSIS:

GALLBLADDER (Q)
GROSS DIAGNOSIS:
- CHOLELITHIASIS

FINAL DIAGNOSIS:

RIGHT URETER (A):
FROZEN SECTION DIAGNOSIS:
- NO TUMOR IDENTIFIED
FINAL DIAGNOSIS:
- BENIGN URETER
- NO TUMOR IDENTIFIED

LEFT URETER (B):
FROZEN SECTION DIAGNOSIS:
- NO TUMOR IDENTIFIED
FINAL DIAGNOSIS:
- BENIGN URETER
- NO TUMOR IDENTIFIED

URETHRA (C):
FROZEN SECTION DIAGNOSIS:
- NO TUMOR IDENTIFIED
FINAL DIAGNOSIS:
- NO TUMOR IDENTIFIED

BLADDER, UTERUS, BILATERAL OVARIES, FALLOPIAN TUBES AND PERIVESICAL NODES (C):

BLADDER:
- POORLY DIFFERENTIATED TRANSITIONAL CELL CARCINOMA, HIGH NUCLEAR GRADE
3/4, INVADING DEEP MUSCLE (OUTER HALF)
- CARCINOMA IN SITU
- SURGICAL MARGINS ARE UNINVOLVED BY CARCINOMA
- VASCULAR SPACE INVASION IDENTIFIED
- CYSTITIS GLANDULARIS

Printed by:
Printed on:

Page 5 of 7
(Continued)

[page 6 of 7]
SURGICAL PATHOLOGY

* Final Report *

- NO UTERUS INVASION SEEN

UTERUS, OVARIES:

- CHRONIC CERVICITIS
- BENIGN ENDOMETRIAL POLYP AND INACTIVE ENDOMETRIUM
- LEIOMYOMA
- SEROSA SHOWING NO SIGNIFICANT PATHOLOGIC CHANGE
- BILATERAL OVARIES AND FALLOPIAN TUBES SHOWING BENIGN PHYSIOLOGIC CHANGES

RIGHT PERIAORTIC LYMPH NODES (D):

- NO TUMOR IDENTIFIED IN FOUR LYMPH NODES (0/4)

RIGHT COMMON ILIAC LYMPH NODES (E):

- NO TUMOR IDENTIFIED IN TWO LYMPH NODES (0/2)

RIGHT EXTERNAL ILIAC LYMPH NODES (F):

- NO TUMOR IDENTIFIED IN FOUR LYMPH NODES

RIGHT OBTURATOR LYMPH NODES (G):

- NO TUMOR IDENTIFIED IN SEVENTEEN LYMPH NODES (0/17)

LEFT PARA-AORTIC LYMPH NODES (H):

- NO TUMOR IDENTIFIED IN 8 LYMPH NODES (0/8)

PRESACRAL LYMPH NODES (I):

- NO TUMOR IDENTIFIED IN 6 LYMPH NODES (0/6)

LEFT COMMON ILIAC LYMPH NODES (J):

- NO TUMOR IDENTIFIED IN FIVE LYMPH NODES (0/5)

LEFT EXTERNAL ILIAC LYMPH NODES (K):

- NO TUMOR IDENTIFIED IN FOUR LYMPH NODES (0/4)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (L):

- NO TUMOR IDENTIFIED IN FOUR 8 NODES (0/8)

RIGHT PRESACIAL LYMPH NODES (M):

- NO TUMOR IDENTIFIED IN THREE LYMPH NODES (0/3)

LEFT PRESACIAL LYMPH NODE (N):

- NO TUMOR IDENTIFIED IN ONE LYMPH NODE (0/1)

LEFT PROXIMAL URETER (O):

- BENIGN URETER
- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

Printed by:
Printed on:

Page 6 of 7
(Continued)

[page 7 of 7]
* Final Report *

RIGHT PROXIMAL URETER (P):

- BENIGN URETER
- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

GALLBLADDER (Q)

GROSS DIAGNOSIS:

- CHOLELITHIASIS

FINAL DIAGNOSIS:

- CHRONIC CHOLECYSTITIS AND CHOLELITHIASIS

pT2bNoMo

CLINICAL DIAGNOSIS:

Bladder cancer

Printed by:
Printed on:

Page 7 of 7
(End of Report)

Source: NCI Genomic Data Commons file 8e59aefb-57e5-4418-ba7f-de3c0dd6855b (TCGA-XF-A9SH.E84E385B-B56A-48AC-AD5B-EA7BE9E69CDE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).